Somatic mutation profile of tumor specimen TCGA-DH-A669-02A (aliquot TCGA-DH-A669-02A-11D-A31L-08) from TCGA case TCGA-DH-A669, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.7 years (25,809 days).
Specimen TCGA-DH-A669-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9123e86d-5833-4a8d-a8d5-1d1b290b3ce6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A669-10A (Blood Derived Normal), aliquot TCGA-DH-A669-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61472b56-3151-4c1e-b9ae-ab5a129f0fe9

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/72 reads (57%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA7 | c.4264C>T p.R1422* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as rs999041739, COSV99566277; called by muse, mutect2
- ABCC11 | c.3461C>A p.T1154K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100750965; called by muse, mutect2, varscan2
- ACHE | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53816427; called by muse, mutect2, varscan2
- BOD1L1 | c.7631G>A p.G2544E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1208256175, COSV99239860; called by muse, mutect2, varscan2
- BTBD7 | c.173dup p.R59Efs*14 | Frame Shift Ins (INS) | VAF 28/126 reads (22%) | catalogued as rs752512017; called by mutect2, varscan2
- CD300LF | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV100042822; called by muse, mutect2, varscan2
- CDH12 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101202942; called by muse, mutect2, varscan2
- CMAS | c.221G>C p.W74S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99982707; called by muse, mutect2, varscan2
- COL24A1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100994218; called by muse, mutect2, varscan2
- CROCC | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.402); catalogued as rs748300745, COSV65013952; called by muse, mutect2, varscan2
- CSF2RA | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV100818024; called by muse, mutect2, varscan2
- CUX1 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99473560; called by muse, mutect2
- DNAH5 | c.11534G>A p.R3845H | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs1181350575, COSV54210853; called by muse, mutect2, varscan2
- DOCK3 | c.4120G>T p.V1374L | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV56527688, COSV99811526; called by muse, mutect2, varscan2
- DPY19L4 | c.637T>G p.S213A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV101363381; called by muse, mutect2, varscan2
- DYNC1I2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99784079; called by muse, mutect2, varscan2
- DYRK1A | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs374771208; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD2 | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs1247010774, COSV99622389; called by muse, mutect2, varscan2
- FLRT2 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.76); catalogued as COSV100420681; called by muse, mutect2, varscan2
- FRAS1 | c.11359T>A p.F3787I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99356852; called by muse, mutect2, varscan2
- GIMAP7 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs199951983, COSV100543700; called by muse, mutect2, varscan2
- GRIN2C | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99501666; called by muse, mutect2
- GRM2 | c.2545+2T>A p.X849_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99622998; called by muse, mutect2, varscan2
- HAUS1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV99959056; called by muse, mutect2, varscan2
- ITPR3 | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577602247, COSV100967646; called by muse, mutect2, varscan2
- KRT6C | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360081; called by muse, mutect2, varscan2
- L3MBTL4 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 82/102 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99529920; called by muse, mutect2, varscan2
- LYPD6B | c.202G>A p.A68T (on ENST00000409029 / NM_001317004.1; = p.A92T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs746167432, COSV54519320; called by muse, mutect2, varscan2
- MYBPC2 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748773939, COSV100731738; called by mutect2, varscan2
- NOL4L | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779165706, COSV100675542; called by muse, mutect2, varscan2
- NOL6 | c.3211C>T p.L1071F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53043023; called by muse, mutect2, varscan2
- NPIPB15 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.107); catalogued as rs760667269, COSV70438555; called by muse, mutect2, varscan2
- NTRK1 | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1340832515, COSV100693581; called by muse, mutect2
- PARP12 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs761991030, COSV99694184; called by muse, mutect2, varscan2
- RAB27A | c.526A>T p.M176L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs757760608, COSV100389434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM46 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55977570; called by muse, mutect2, varscan2
- SEMA3E | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs1192155437, COSV100319057; called by muse, mutect2, varscan2
- STRA6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100121365; called by muse, mutect2
- SZT2 | c.5088+1G>A p.X1696_splice (on ENST00000634258 / NM_001365999.1; = p.X1639_splice on NM_015284.4) | Splice Site (SNP) | VAF 62/77 reads (81%) | catalogued as COSV100987484; called by muse, mutect2, varscan2
- TDRD6 | c.4241T>C p.L1414S | Missense Mutation (SNP) | VAF 118/220 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100287927; called by muse, mutect2, varscan2
- TFEC | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.338); catalogued as COSV55398415; called by muse, mutect2, varscan2
- TG | c.7784A>G p.D2595G | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV99601973; called by muse, mutect2, varscan2
- UGT1A8 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs549093448, COSV100990574; called by muse, mutect2, varscan2
- ZDHHC14 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100399327; called by muse, mutect2, varscan2
- ZIC4 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268053; called by muse, mutect2, varscan2
- LGALS3 | c.7_10del p.D3Ifs*111 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | called by mutect2, pindel, varscan2
- SETD2 | c.7037_7040dup p.Q2347Hfs*23 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.111G>T p.L37= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100119280; called by muse, mutect2
- CCDC185 | c.1812C>T p.S604= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100838814; called by muse, mutect2, varscan2
- DAAM1 | c.330C>G p.L110= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV62837568; called by muse, mutect2, varscan2
- DDX19A | c.912T>C p.D304= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs1065168; called by muse, mutect2, varscan2
- ERN2 | c.612C>T p.C204= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs774207313, COSV99891873; called by muse, mutect2, varscan2
- GUCY2C | c.117C>G p.V39= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99664320; called by muse, mutect2, varscan2
- H1-4 | c.108T>A p.S36= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV99175299; called by muse, mutect2, varscan2
- IDE | c.2988C>A p.T996= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs764149128, COSV99794553; called by muse, mutect2, varscan2
- IGLV3-12 | c.102A>G p.A34= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- LAMB2 | c.3756C>T p.A1252= | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as rs773560262, COSV100026334; called by muse, mutect2, varscan2
- NEK11 | c.1800C>T p.S600= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs147225516; called by muse, mutect2, varscan2
- NOL4L | c.1221G>A p.V407= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV100675656; called by muse, mutect2, varscan2
- RHBDF1 | c.1740C>T p.S580= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs770682385, COSV51957535; called by muse, mutect2, varscan2
- TUBA3D | c.888C>T p.F296= | Silent (SNP) | VAF 65/309 reads (21%) | catalogued as rs532066293, COSV58310581; called by muse, mutect2, varscan2
- DEFB119 | c.62-928G>T | Intron (SNP) | VAF 22/238 reads (9%) | catalogued as COSV53620589; called by muse, mutect2
